Somatic mutation profile of tumor specimen 0DSG2G from CCDI case PBCICP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,575 days).
Specimen 0DSG2G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59a808f7-00f7-4852-a11c-ec77c300e10b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSG2N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2c0c1d3-4bc0-4983-ab11-cf5a5c76a7a3

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FYCO1 | c.2293C>G p.R765G | Missense Mutation (SNP) | VAF 190/383 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs372227118; called by muse, mutect2, varscan2
- MRPL10 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 194/408 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs372584381; called by muse, mutect2, varscan2
- OR2J2 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 170/459 reads (37%) | catalogued as rs201438710; called by muse, mutect2, varscan2
- SLC8A1 | c.2316C>T p.S772= | Silent (SNP) | VAF 193/450 reads (43%) | called by muse, mutect2, varscan2
- STAT1 | c.135C>T p.H45= | Silent (SNP) | VAF 147/306 reads (48%) | catalogued as rs566696388, COSV63117126, COSV63117893; called by muse, mutect2, varscan2
- SAR1A | c.178+95T>C | Intron (SNP) | VAF 73/190 reads (38%) | catalogued as rs1357471689; called by muse, mutect2, varscan2
